Surgical pathology report (de-identified scan), TCGA case TCGA-06-1802, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-1802-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

TCGA-06-1802

CLINICAL HISTORY

Brain tumor.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, excision biopsy

B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, deep cerebral tumor, excision: Glioblastoma (WHO Grade IV)
(see comment).

COMMENT

Sections show a high-grade glial tumor characterized by cells with elongated and angulated nuclei and gemistocytes. Mitotic figures are frequent and vascular proliferation is present.

The tumor is diffusely p53 immunopositive.

The Ki-67 labeling index is approximately 80%.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered:

Date Reported:

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on paraffin tissue block

TE DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed

[page 2 of 3]
[REDACTED]

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FD/ COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED] TCGA-06-1802

INTRA-OPERATIVE CONSULTATION

A. Brain, excision biopsy: Atypical glial proliferation, consistent with glioma. Frozen section and smears performed at [REDACTED] hospital and results reported to the Physician of Record. [REDACTED]

GROSS DESCRIPTION

A. Received are one red hemorrhagic tissue fragment, 0.6 x 0.5 x 0.4, and one tan friable tissue fragment, 0.5 x 0.4 x 0.3. FS and smears are performed. A1: fr([REDACTED] residual; A2: unfrozen tissue. A small sample is also placed in glutaraldehyde.

B.

SPECIMEN: Brain tumor.

FIXATIVE: Formalin.

GENERAL: Received are six irregular, gray-white-tan and hemorrhagic fragments of brain tissue, .3-.7 cm.

SECTIONS: All submitted in B1 and B2.

ICD-9(s):

239.6 239.6

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
H/E x 1		1		
H/E x 1		2		
H/E ~ 1		3		

Part B: Brain, excision biopsy

Taken:

Requested by:

[page 3 of 3]
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
Rct 1 H/E x 1	1		
H/I 1	2		
KeratinSu x 1	2		
MGMT x 1	2		
MIB1-DA x 1	2		
P53DO7 x 1	2		
P63-NE x 1	2		
Rct 1 H/E x 1	2		
Rct 2 H/E x 1	2		

TCGA-06-1802

*** End of Report ***

Source: NCI Genomic Data Commons file 357655f5-6389-44ea-bee3-61950be2ea21 (TCGA-06-1802.DD1001F7-1C3B-42EB-B7DD-E83024399F85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).